Somatic mutation profile of tumor specimen SM-JU334 (aliquot 7316UP-1220) from CPTAC case C464694, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen SM-JU334: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9740b864-0bee-4929-bc73-d14a1e0103e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105273 (Blood Derived Normal), aliquot 7316UP-1220-1105273; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b670b4c-a4f6-40a7-a573-b91a66b3d189

The open-access MAF lists 84 somatic variants for this specimen: 54 protein-altering or splice-affecting, 17 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 17, Intron 6, Nonsense Mutation 5, RNA 3, 5'UTR 3, Splice Site 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 87/230 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 44/163 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 426/500 reads (85%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOT9 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs771016382; called by muse, mutect2, varscan2
- ARAP3 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs747769367; called by muse, mutect2, varscan2
- ARHGEF5 | c.697C>A p.Q233K | Missense Mutation (SNP) | VAF 28/856 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV50221472; called by muse, mutect2
- B3GLCT | c.650T>G p.L217* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | catalogued as rs1481842523; called by muse, mutect2
- COL1A2 | c.3200G>A p.R1067H | Missense Mutation (SNP) | VAF 138/669 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs530026906, COSV51955410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.12049G>A p.V4017M | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1206121954, COSV54202849; called by muse, mutect2, varscan2
- DYNC2H1 | c.10772C>T p.T3591M | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.234); catalogued as rs370617490; called by muse, mutect2, varscan2
- ERN1 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs1202226977; called by muse, mutect2
- FBXO34 | c.2054A>G p.N685S | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1566569899; called by muse, mutect2, varscan2
- FLNB | c.6577G>A p.A2193T | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781114131, COSV55884851; called by muse, mutect2
- FTMT | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.551); catalogued as rs1400684823, COSV58419742; called by muse, mutect2, varscan2
- GABRE | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 107/260 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs553890653, COSV64819053; called by muse, mutect2, varscan2
- GRM4 | c.2305G>A p.V769M | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs780548540; called by muse, mutect2, varscan2
- LHFPL1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs762194253, COSV64333341; called by muse, mutect2, varscan2
- MUC16 | c.5069G>T p.G1690V | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.301); catalogued as COSV101199304; called by muse, mutect2, varscan2
- OR2T2 | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 109/1146 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs762818466; called by muse, varscan2
- PNLIPRP1 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs114165255; called by muse, mutect2, varscan2
- SLC4A1 | c.1910G>A p.G637D | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs769977105; called by muse, mutect2, varscan2
- UBQLNL | c.669G>T p.L223F | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs564556578, COSV66493216; called by muse, mutect2, varscan2
- ZBTB20 | c.638G>A p.R213Q (on ENST00000474710 / NM_001164342.2; = p.R140Q on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/265 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1195464738, COSV61851404; called by muse, mutect2, varscan2
- ABCA1 | c.230C>G p.A77G | Missense Mutation (SNP) | VAF 71/347 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ANKFY1 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ARMCX2 | c.773A>G p.K258R | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2A3 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 30/712 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- AVIL | c.1956G>A p.W652* | Nonsense Mutation (SNP) | VAF 1547/1640 reads (94%) | called by muse, mutect2, varscan2
- CCN1 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 112/525 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- COQ8B | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 19/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX11 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 204/4050 reads (5%) | called by muse, mutect2
- DNAH1 | c.6736G>A p.A2246T | Missense Mutation (SNP) | VAF 13/317 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- EFCAB3 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM124A | c.538del p.Y180Tfs*13 (on ENST00000322475 / NM_001242312.2; = p.Y216Tfs*13 on NM_145019.4) | Frame Shift Del (DEL) | VAF 142/340 reads (42%) | called by mutect2, pindel, varscan2
- FSIP2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT tolerated (0.11); called by muse, mutect2, varscan2
- GJA1 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- HCRTR2 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 94/425 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HPD | c.1155G>C p.E385D | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HTATSF1 | c.1510A>C p.K504Q | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNN3 | c.1919C>G p.A640G (on ENST00000618040 / NM_001204087.1; = p.A625G on NM_002249.6) | Missense Mutation (SNP) | VAF 104/552 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- KIF21B | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LCE2C | c.121T>C p.F41L | Missense Mutation (SNP) | VAF 137/318 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO1F | c.988T>C p.W330R | Missense Mutation (SNP) | VAF 13/281 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRC5 | c.2191A>G p.I731V | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PGM2 | c.454T>G p.S152A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIR | c.570G>A p.W190* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- PRKCA | c.1153A>G p.M385V | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2
- RBP3 | c.1784T>C p.V595A | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SUN3 | c.1008G>C p.W336C | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TRPM5 | c.1660A>G p.I554V | Missense Mutation (SNP) | VAF 147/193 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TSPAN8 | c.445-2A>G p.X149_splice | Splice Site (SNP) | VAF 51/230 reads (22%) | called by muse, mutect2, varscan2
- URB2 | c.1543T>C p.S515P | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- XCL2 | c.290C>A p.T97N | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ZNF711 | c.35C>A p.T12K | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ADRB3 | c.312G>A p.P104= | Silent (SNP) | VAF 76/380 reads (20%) | called by muse, mutect2, varscan2
- AHNAK2 | c.13956C>A p.I4652= | Silent (SNP) | VAF 63/140 reads (45%) | catalogued as rs771880486, COSV60910825; called by muse, mutect2, varscan2
- COL21A1 | c.780A>C p.T260= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- DENND1A | c.3012G>A p.Q1004= | Silent (SNP) | VAF 32/176 reads (18%) | called by muse, mutect2
- EVC | c.1602C>T p.F534= | Silent (SNP) | VAF 125/606 reads (21%) | catalogued as rs766294209, COSV53831002; called by muse, mutect2, varscan2
- F2RL3 | c.864G>T p.V288= | Silent (SNP) | VAF 41/196 reads (21%) | called by muse, mutect2, varscan2
- FAM120C | c.2736T>A p.T912= | Silent (SNP) | VAF 12/382 reads (3%) | called by muse, mutect2
- FLG | c.3627G>A p.G1209= | Silent (SNP) | VAF 158/799 reads (20%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.624C>T p.D208= | Silent (SNP) | VAF 38/226 reads (17%) | catalogued as rs369654526; called by muse, mutect2, varscan2
- LAIR2 | c.102G>A p.E34= | Silent (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- PUM2 | c.2256T>A p.T752= | Silent (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- RPAP1 | c.141G>A p.R47= | Silent (SNP) | VAF 73/141 reads (52%) | called by muse, mutect2, varscan2
- SYT16 | c.432G>A p.E144= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as rs1482341816, COSV70857532; called by muse, mutect2, varscan2
- TAS2R14 | c.462C>A p.A154= | Silent (SNP) | VAF 743/903 reads (82%) | called by muse, mutect2, varscan2
- TNFSF14 | c.372G>A p.R124= | Silent (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- TSNAXIP1 | c.192G>T p.L64= | Silent (SNP) | VAF 65/164 reads (40%) | called by muse, mutect2, varscan2
- ZIM3 | c.468C>T p.G156= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs758265716; called by muse, mutect2, varscan2
- AC098591.2 | n.1050C>T | RNA (SNP) | VAF 48/271 reads (18%) | catalogued as rs761360875; called by muse, mutect2, varscan2
- CASK | c.278+35T>G | Intron (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- CCBE1 | c.554-83G>A | Intron (SNP) | VAF 129/297 reads (43%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.1358-843T>C | Intron (SNP) | VAF 6/45 reads (13%) | catalogued as rs934500344; called by muse, varscan2
- HERC2P2 | n.2943A>G | RNA (SNP) | VAF 168/322 reads (52%) | called by muse, varscan2
- IGHD1-1 | chr14:105922285 G>T | 5'Flank (SNP) | VAF 36/194 reads (19%) | called by muse, mutect2, varscan2
- LMO2 | c.-340C>T | 5'UTR (SNP) | VAF 4/48 reads (8%) | catalogued as rs1248384002; called by muse, mutect2
- MUC5B | c.-53G>A | 5'UTR (SNP) | VAF 15/53 reads (28%) | catalogued as COSV71594412; called by muse, mutect2, varscan2
- OR7D1P | n.821C>T | RNA (SNP) | VAF 25/162 reads (15%) | called by muse, mutect2, varscan2
- PHEX | c.1966-16C>G | Intron (SNP) | VAF 48/246 reads (20%) | called by muse, mutect2, varscan2
- PSMD5 | c.1006+82A>C | Intron (SNP) | VAF 30/153 reads (20%) | called by muse, mutect2, varscan2
- SLC6A8 | c.777+350G>T | Intron (SNP) | VAF 64/248 reads (26%) | called by muse, mutect2, varscan2
- TUBA1B | c.-38C>G | 5'UTR (SNP) | VAF 31/169 reads (18%) | called by muse, mutect2, varscan2
